ALCHEMIST case ALCH-ADR9 — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/7e0ab8b9-39e8-439b-b046-1c4c13d33047

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 54.5 years (19,894 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-ADR9-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-ADR9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-ADR9-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 38; Percent tumor nuclei: 48; Percent normal cells: 24; Percent necrosis: 18; Percent stromal cells: 20; Percent lymphocyte infiltration: 28; Percent monocyte infiltration: 12; Percent neutrophil infiltration: 1.
